Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9GU, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9GU-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

LIVER, SEGMENT V RESECTION:

Moderately differentiated hepatocellular carcinoma.

The noninvolved liver show macro and microsteatosis with focal dilated sinusoid.

No evidence of cirrhosis. See Key Pathological Findings and see comment

KEY PATHOLOGICAL FINDINGS:

Specimen type:	Liver segmentectomy
Tumor configuration:	Lobulated, subcapsular
Tumor size:	11 x 9 x 7 cm
Histologic type:	Hepatocellular carcinoma
Histologic grade:	Moderately differentiated
Tumor necrosis:	Less than 10%
Parenchymal margin:	Free of tumor
Angiolymphatic invasion:	Not identified
Pathologic stage:	Stage I (T1 Nx Mx)

COMMENT : The liver away from the carcinoma (block A7) show preserved normal framework on reticulin stain. The trichrome stain show no increase in fibrosis and absence of bridging. Iron stain fails to show any increase in iron deposit.

I, _____ the attending pathologist, personally reviewed the entire case and rendered the final diagnosis. Electronically Signed Out by

Specimen(s) Received

A SEGMENT 5 RESECTION FS

Clinical History

None given.

Preoperative Diagnosis

Liver cancer.

Frozen Section Diagnosis

FSA1. SEGMENT 5 RESECTION:

Perpendicular margin is free of tumor.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by _____ in _____ at _____

I, _____, have performed the intraoperative consultation (s) and issued the above diagnosis.

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site Liver NOS
C22.0

QA 4/28/14

[page 2 of 2]
Gross Description

A. The specimen is received fresh labeled "segment 5 resection". The specimen consists of 604.0 gram segmentectomy resection of liver which measures 16.0 x 11.0 x 7.0 cm. The capsule of the specimen is pink-tan to red-brown, focally hemorrhagic, and has bosselated surface. The parenchymal resection margin is tan-red-brown, focally cauterized and is inked blue. The specimen is serially sectioned to reveal an irregular, ill-defined lobulated intraparenchymal tumor mass which measures 11.0 x 9.0 x 7.0 cm. The tumor is bulging capsule and is 1.0 cm from the closest parenchymal resection margin. The tumor mass is focally hemorrhagic and necrotic. The areas of necrosis range from 0.1 to 2.5 cm in greatest dimension, and occupy less than 10% of the tumor. Representative section of the tumor in relation to the closest parenchymal resection margin is submitted for frozen section as FSA1. Representative sections of the specimen are submitted to the Tissue Procurement Laboratory. Additional sections of the specimen are submitted in 6 cassettes as follows:

A2-A5: Tumor bulging capsule
A6: Central part of the tumor
A7: Grossly unremarkable liver parenchyma.

Source: NCI Genomic Data Commons file d3baa567-919e-4aef-ad8a-3f458fb92598 (TCGA-2Y-A9GU.5585C485-B57A-4CA8-A3E3-F093A7E6AC76.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).